Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAF9, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAF9-01A (Primary Tumor).

Department of Pathology

ICD O3
Seminoma NOS 9061/3
Site R Testis NOS C62.9
JW 3/13/14

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 4 cm; tumor confined to testis in available slides; no angio-invasion; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file f6e19e70-0421-43d6-aa42-9336f2a26aee (TCGA-2G-AAF9-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).